FM case AD4102 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/bfb8b93d-4530-43a7-b206-528b3a35c5b3

Male, 61.9 years: Melanoma, NOS (ICD-O-3 8720/3) of the eye; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
